Somatic mutation profile of tumor specimen TCGA-VS-A9UA-01A (aliquot TCGA-VS-A9UA-01A-11D-A42O-09) from TCGA case TCGA-VS-A9UA, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 60.8 years (22,221 days).
Specimen TCGA-VS-A9UA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1faaa7e3-8f9d-47ba-8ebf-8ac7ed6e60a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A9UA-10A (Blood Derived Normal), aliquot TCGA-VS-A9UA-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c70dd870-7407-429b-93de-a5679737d1ce

The open-access MAF lists 204 somatic variants for this specimen: 143 protein-altering or splice-affecting, 55 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 116, Silent 55, Nonsense Mutation 19, Splice Region 4, 5'Flank 2, Splice Site 2, RNA 2, Frame Shift Del 1, 3'UTR 1, Intron 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 20/104 reads (19%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.839G>C p.R280T | Missense Mutation (SNP) | VAF 6/27 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2
- AADAT | c.903C>G p.L301= | Splice Region (SNP) | VAF 24/87 reads (28%) | catalogued as COSV100528616; called by muse, mutect2, varscan2
- AASDH | c.2981T>G p.F994C | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.038); catalogued as COSV99221143; called by muse, mutect2, varscan2
- AC109583.1 | c.273C>G p.F91L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs1195077891, COSV100167862, COSV59350198, COSV59351457; called by muse, mutect2, varscan2
- ACSL6 | c.1991C>G p.S664* (on ENST00000379240; = p.S689* on NM_015256.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as COSV99733445; called by muse, mutect2, varscan2
- AFF4 | c.1641G>C p.Q547H | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.995); catalogued as COSV99534844; called by muse, mutect2
- AKAP12 | c.2368G>C p.E790Q | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99483035; called by muse, mutect2, varscan2
- AKAP5 | c.988G>C p.E330Q | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100278073, COSV57742507; called by muse, mutect2
- AKNAD1 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs751500049, COSV62197104; called by muse, mutect2, varscan2
- ANKRD17 | c.6334C>A p.P2112T | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); catalogued as COSV58221348; called by muse, mutect2, varscan2
- AQP8 | c.566C>G p.S189C | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99563887; called by muse, mutect2
- ASB3 | c.661C>T p.Q221* | Nonsense Mutation (SNP) | VAF 14/51 reads (27%) | catalogued as COSV99711940; called by muse, mutect2, varscan2
- ASPM | c.9493C>T p.H3165Y | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.053); catalogued as COSV99660147, COSV99661094; called by muse, mutect2, varscan2
- BIN1 | c.1232C>G p.S411C | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.62); catalogued as COSV99387880; called by muse, mutect2, varscan2
- BPNT2 | c.841G>T p.D281Y | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.832); catalogued as COSV99388979; called by muse, mutect2, varscan2
- C2CD4A | c.203G>A p.W68* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as rs777756585, COSV100831056; called by muse, varscan2
- CALD1 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.247); catalogued as rs1388047889, COSV100724173; called by muse, mutect2, varscan2
- CAMSAP1 | c.3962G>A p.R1321H | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100409468, COSV56728851; called by muse, mutect2, varscan2
- CASP8 | c.661-1G>A p.X221_splice (on ENST00000432109 / NM_033355.3; = p.X238_splice on NM_001228.4) | Splice Site (SNP) | VAF 19/78 reads (24%) | catalogued as COSV51853527; called by muse, varscan2
- CASP8 | c.698G>A p.R233Q (on ENST00000432109 / NM_033355.3; = p.R250Q on NM_001228.4) | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); catalogued as rs771150445, COSV51844924; ClinVar: uncertain significance; called by muse, varscan2
- CCDC190 | c.437G>A p.R146K | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV100905822; called by muse, mutect2, varscan2
- CCDC85A | c.968G>A p.G323E | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); catalogued as COSV101339456; called by muse, mutect2, varscan2
- CD101 | c.2855C>T p.S952L | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as rs768942188, COSV99869240; called by muse, mutect2, varscan2
- CDC42SE1 | c.40G>C p.E14Q | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.306); catalogued as COSV100603358; called by muse, mutect2, varscan2
- CENPC | c.1024C>T p.Q342* | Nonsense Mutation (SNP) | VAF 22/79 reads (28%) | catalogued as COSV99893819; called by muse, mutect2, varscan2
- CEP135 | c.2896G>C p.E966Q | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV99954341; called by muse, mutect2, varscan2
- CEP152 | c.2587C>T p.H863Y | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.051); catalogued as rs750725606, COSV100358707; called by muse, mutect2, varscan2
- CEP164 | c.181G>C p.E61Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.112); catalogued as COSV99633129; called by muse, mutect2, varscan2
- CFAP47 | c.5402C>T p.A1801V | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.377); catalogued as COSV100545264; called by muse, mutect2, varscan2
- CHMP7 | c.781G>T p.E261* | Nonsense Mutation (SNP) | VAF 3/40 reads (8%) | catalogued as COSV57532838; called by muse, mutect2
- CNST | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 12/76 reads (16%) | catalogued as COSV100829845; called by muse, mutect2, varscan2
- CNTN4 | c.2159G>A p.W720* | Nonsense Mutation (SNP) | VAF 17/82 reads (21%) | catalogued as COSV100639176; called by muse, mutect2, varscan2
- CYP2C9 | c.1261A>C p.K421Q | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV99582595; called by muse, mutect2, varscan2
- DCAF5 | c.1857G>C p.Q619H | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.809); catalogued as COSV100432401; called by muse, mutect2, varscan2
- DGKG | c.1810G>C p.E604Q | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.854); catalogued as COSV99403103, COSV99404053; called by muse, mutect2
- DGKK | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as rs373977703, COSV65708353; called by muse, mutect2, varscan2
- DLG2 | c.2440G>A p.E814K | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV54655615; called by muse, mutect2, varscan2
- DMD | c.1682G>A p.W561* | Nonsense Mutation (SNP) | VAF 23/63 reads (37%) | catalogued as CM013364, COSV99921588; called by muse, mutect2, varscan2
- DSP | c.2719C>T p.R907C | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.759); catalogued as rs749051278, COSV65792211; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EGFR | c.528G>C p.M176I | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99290048; called by muse, mutect2
- ELOA2 | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.029); catalogued as rs149432716; called by muse, mutect2
- ELSPBP1 | c.558C>G p.F186L | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100353587; called by muse, mutect2, varscan2
- EP300 | c.708G>C p.L236F | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV99608281; called by muse, mutect2, varscan2
- FANCI | c.1702C>A p.H568N | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as COSV100167848; called by muse, mutect2, varscan2
- FAT2 | c.2489C>T p.S830L | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.73); PolyPhen benign (0.431); catalogued as rs373851434; called by muse, mutect2, varscan2
- FAU | c.79C>G p.H27D | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV99658063; called by muse, mutect2, varscan2
- FBXW7 | c.1491G>C p.L497F (on ENST00000281708 / NM_001349798.2; = p.L417F on NM_018315.5) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.697); catalogued as COSV99656285; called by muse, varscan2
- FMO5 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs373414071; called by muse, mutect2, varscan2
- FTSJ1 | c.975G>A p.M325I | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as COSV99191393; called by muse, mutect2, varscan2
- FUNDC1 | c.302G>C p.R101T | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV100953634, COSV65181304; called by muse, mutect2, varscan2
- FZD6 | c.1408C>T p.R470* | Nonsense Mutation (SNP) | VAF 23/88 reads (26%) | catalogued as rs750436184, COSV100708357; called by muse, mutect2, varscan2
- GABRA4 | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1323522580, COSV99973906; called by muse, mutect2, varscan2
- GANAB | c.392C>G p.S131C | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100647994; called by muse, mutect2, varscan2
- GLS | c.1256C>G p.S419C | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100289977; called by muse, mutect2, varscan2
- H2BC14 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV60798056; called by muse, mutect2, varscan2
- HENMT1 | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV100898653; called by muse, mutect2, varscan2
- HLA-A | c.284C>G p.S95* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as COSV65136846; called by muse, mutect2, varscan2
- ID3 | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs1276585913, COSV101000762; called by muse, mutect2, varscan2
- IPO4 | c.3030G>C p.Q1010H | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV100268983; called by muse, mutect2, varscan2
- IRS4 | c.2200C>G p.R734G | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as COSV100929523; called by muse, mutect2, varscan2
- ITPKC | c.378G>C p.W126C | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99648658; called by muse, mutect2, varscan2
- ITPR2 | c.7636G>A p.D2546N | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101189945; called by muse, mutect2, varscan2
- ITPR3 | c.2975C>T p.S992F | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100967266; called by muse, mutect2, varscan2
- KCNH5 | c.2188G>A p.E730K | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV59773187; called by muse, mutect2
- KDM4B | c.933G>T p.K311N | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99346233; called by muse, mutect2
- KIR2DL3 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 9/215 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1409527871; called by muse, mutect2
- KLHL4 | c.1978C>T p.R660* | Nonsense Mutation (SNP) | VAF 40/144 reads (28%) | catalogued as COSV100909463; called by muse, mutect2, varscan2
- KLHL6 | c.1859C>G p.S620C | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.536); catalogued as COSV100384540; called by muse, mutect2, varscan2
- KMT2D | c.2107G>A p.E703K | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs1363389206, COSV99980479; called by muse, mutect2, varscan2
- LPCAT1 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV99358943; called by muse, mutect2, varscan2
- LRIT1 | c.1850G>A p.R617K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.8); PolyPhen benign (0.029); catalogued as COSV100928070, COSV64513222; called by muse, mutect2
- LZTS2 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs748135931, COSV100932151, COSV64653196; called by muse, mutect2, varscan2
- MAST4 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.103); catalogued as COSV101282532; called by muse, mutect2, varscan2
- MAST4 | c.5216G>A p.R1739Q (on ENST00000403625 / NM_001164664.2; = p.R1550Q on NM_015183.3) | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.306); catalogued as rs373260425; called by muse, mutect2, varscan2
- MDN1 | c.2833C>T p.R945W | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV101020926; called by muse, mutect2, varscan2
- METAP2 | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.421); catalogued as COSV54150082; called by muse, mutect2, varscan2
- MUC16 | c.42249C>G p.I14083M | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV101109849, COSV66689721; called by muse, mutect2
- MUC17 | c.6770C>A p.A2257D | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV100072832, COSV60299890; called by muse, mutect2, varscan2
- MYO1D | c.1510C>T p.R504* | Nonsense Mutation (SNP) | VAF 21/67 reads (31%) | catalogued as rs1166652823, COSV59017933; called by muse, mutect2, varscan2
- N6AMT1 | c.560A>T p.K187M | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV100374963, COSV58136145; called by muse, mutect2, varscan2
- NDEL1 | c.202G>C p.D68H | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as COSV100232921; called by muse, mutect2, varscan2
- NKD2 | c.639G>C p.R213S | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV99724016; called by muse, mutect2, varscan2
- NLGN1 | c.741C>G p.F247L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.042); catalogued as COSV100849216, COSV100849520, COSV64346935; called by muse, mutect2, varscan2
- NMRK1 | c.403C>T p.Q135* | Nonsense Mutation (SNP) | VAF 5/49 reads (10%) | catalogued as COSV100737968; called by muse, mutect2
- OR2S2 | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100558537, COSV100558782; called by muse, mutect2, varscan2
- OR4D9 | c.597G>T p.M199I | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.084); catalogued as COSV61434165; called by muse, mutect2
- P3H3 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.92); catalogued as rs1242921806, COSV51831998; called by muse, mutect2, varscan2
- PARP3 | c.1014G>A p.V338= | Splice Region (SNP) | VAF 28/42 reads (67%) | catalogued as COSV99232355; called by muse, mutect2, varscan2
- PCDHB5 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.014); catalogued as COSV50649167; called by muse, mutect2, varscan2
- PDGFRL | c.1117G>C p.E373Q | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV99286310; called by muse, mutect2, varscan2
- PEMT | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376787997; called by muse, mutect2, varscan2
- PFN1 | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as CM133997, COSV99337325; called by muse, mutect2, varscan2
- PGLYRP2 | c.1644T>A p.T548= | Splice Region (SNP) | VAF 9/33 reads (27%) | catalogued as COSV99483949; called by muse, mutect2, varscan2
- PHF23 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); catalogued as rs1377384334, COSV99138464; called by muse, mutect2, varscan2
- PHLDB2 | c.2257G>A p.E753K (on ENST00000393925 / NM_001134439.2; = p.E710K on NM_145753.2) | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV67308813, COSV67311245; called by muse, mutect2, varscan2
- PIK3IP1 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV53223001, COSV99314007; called by muse, mutect2, varscan2
- PLAU | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.59); catalogued as COSV65641382; called by muse, mutect2, varscan2
- PLCB3 | c.1349G>A p.G450D | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV99657330; called by muse, mutect2, varscan2
- PLK3 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV100221129, COSV59501628; called by muse, mutect2, varscan2
- PRKCG | c.1420C>G p.Q474E | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV54733942, COSV99668883; called by muse, mutect2, varscan2
- PSMD2 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV59531094; called by muse, mutect2, varscan2
- RAI1 | c.943G>A p.G315R | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as rs1240704009, COSV55395852; called by muse, mutect2, varscan2
- RASAL1 | c.808C>T p.L270F | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV99921642; called by muse, mutect2, varscan2
- RB1 | c.769C>T p.Q257* | Nonsense Mutation (SNP) | VAF 18/53 reads (34%) | catalogued as CM030498, COSV57294911; called by muse, mutect2, varscan2
- RFX4 | c.1381G>C p.D461H (on ENST00000392842 / NM_213594.3; = p.D367H on NM_032491.6) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99985746; called by muse, mutect2, varscan2
- RGS1 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1371749345, COSV100817442; called by muse, mutect2, varscan2
- RHOBTB2 | c.2183G>C p.*728Sext*7 | Nonstop Mutation (SNP) | VAF 14/23 reads (61%) | catalogued as COSV99310888; called by muse, mutect2, varscan2
- RIPK3 | c.136G>C p.D46H | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV53475052, COSV53475507, COSV99353162; called by muse, mutect2, varscan2
- RLN2 | c.59C>G p.S20C | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV100395758; called by muse, mutect2, varscan2
- RNF25 | c.1339C>T p.R447W | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs772330341, COSV99828936; called by muse, mutect2, varscan2
- RPS20 | c.117G>C p.L39F | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV99154851; called by muse, mutect2, varscan2
- SCN10A | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101479365; called by muse, mutect2, varscan2
- SCTR | c.607G>C p.D203H | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.152); catalogued as COSV99191563; called by muse, mutect2, varscan2
- SELENOI | c.845C>G p.S282* | Nonsense Mutation (SNP) | VAF 15/62 reads (24%) | catalogued as COSV99564373; called by muse, mutect2, varscan2
- SIGLEC14 | c.1011G>C p.Q337H | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs1302621099, COSV99707421; called by muse, mutect2
- SLC18A1 | c.679C>T p.R227* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as rs200394019, COSV99368489, COSV99369007; called by muse, mutect2, varscan2
- SLC41A1 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as rs764642616, COSV65650321; called by muse, mutect2, varscan2
- SOX14 | c.242G>C p.R81P | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100048097, COSV100048162; called by muse, mutect2, varscan2
- SPSB1 | c.473G>A p.S158N | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV100049389; called by muse, mutect2, varscan2
- STXBP5 | c.2662G>A p.D888N (on ENST00000321680 / NM_001127715.2; = p.D852N on NM_139244.4) | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.22); catalogued as COSV99470048; called by muse, mutect2, varscan2
- SUPT20H | c.560G>A p.W187* (on ENST00000350612 / NM_001014286.3; = p.W188* on NM_017569.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 27/70 reads (39%) | catalogued as COSV100634648; called by muse, mutect2, varscan2
- TAC1 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV100071099; called by muse, mutect2, varscan2
- TAF1L | c.2809G>C p.D937H | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99644523; called by muse, mutect2, varscan2
- TET3 | c.3004C>T p.R1002C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101327765; called by muse, mutect2, varscan2
- TFDP2 | c.286G>A p.E96K (on ENST00000489671 / NM_001178139.2; = p.E35K on NM_006286.5) | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.76); catalogued as COSV100050828; called by muse, mutect2, varscan2
- TM4SF19 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV99879344; called by muse, mutect2, varscan2
- TRAF3 | c.928C>T p.R310* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as COSV61026797; called by muse, mutect2, varscan2
- TRPC5 | c.337G>C p.E113Q | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99460509; called by muse, mutect2
- TTBK1 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52489697; called by muse, mutect2, varscan2
- TTC14 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.251); catalogued as rs1560073244, COSV56010033, COSV99931989; called by muse, mutect2, varscan2
- TUBGCP4 | c.1417G>A p.E473K (on ENST00000260383 / NM_001286414.3; = p.E472K on NM_014444.5) | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV99539004; called by muse, mutect2, varscan2
- UNK | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.079); catalogued as rs1470788480, COSV99504871; called by muse, mutect2, varscan2
- USF3 | c.4531C>T p.Q1511* | Nonsense Mutation (SNP) | VAF 12/67 reads (18%) | catalogued as COSV57074220; called by muse, mutect2, varscan2
- WFDC3 | c.680-1G>C p.X227_splice | Splice Site (SNP) | VAF 5/20 reads (25%) | catalogued as COSV99714533; called by muse, mutect2
- XPO1 | c.3196C>G p.P1066A | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV101294199; called by muse, mutect2, varscan2
- ZNF138 | c.393G>C p.L131F (on ENST00000307355 / NM_001367572.1; = p.L105F on NM_006524.4) | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.299); catalogued as COSV100245698; called by muse, mutect2, varscan2
- ZNF229 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.392); catalogued as COSV99350338; called by muse, mutect2, varscan2
- ZNF311 | c.398T>C p.L133P | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV101014116; called by muse, mutect2, varscan2
- ZNF442 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV54421875; called by muse, mutect2, varscan2
- ZNF638 | c.2430G>A p.G810= | Splice Region (SNP) | VAF 31/91 reads (34%) | catalogued as COSV100038563; called by muse, mutect2, varscan2
- DMXL2 | c.6550C>A p.Q2184K | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.187); called by muse, mutect2
- FRYL | c.7923_7930del p.S2642Vfs*2 | Frame Shift Del (DEL) | VAF 23/76 reads (30%) | called by mutect2, pindel*, varscan2*
- ADARB2 | c.1386A>G p.R462= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as COSV101186860; called by muse, mutect2, varscan2
- AKNAD1 | c.2205G>C p.V735= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV100645479; called by muse, mutect2
- ALDH3A1 | c.1026C>T p.I342= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as rs761187992, COSV99855850; called by muse, mutect2, varscan2
- ANKRD36B | c.1416C>G p.V472= | Silent (SNP) | VAF 58/248 reads (23%) | catalogued as COSV99308140; called by muse, mutect2, varscan2
- ARL6IP6 | c.381C>T p.I127= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs755057691, COSV100423955; called by muse, mutect2, varscan2
- CALD1 | c.270G>T p.G90= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV100724171; called by muse, mutect2
- CLASP1 | c.3600G>C p.L1200= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV99754365; called by muse, mutect2, varscan2
- CRPPA | c.783C>G p.L261= (on ENST00000407010 / NM_001368197.1; = p.L211= on NM_001101417.4) | Silent (SNP) | VAF 4/72 reads (6%) | catalogued as COSV101235362; called by muse, mutect2
- DRD2 | c.846G>A p.E282= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV100669519; called by muse, mutect2, varscan2
- EBF3 | c.390C>T p.L130= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as COSV100799151, COSV62475154; called by muse, mutect2, varscan2
- ELMO3 | c.438G>A p.Q146= (on ENST00000652269; = p.Q93= on NM_024712.5) | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100681556; called by muse, mutect2, varscan2
- FASN | c.7248G>C p.L2416= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV100147660; called by muse, mutect2
- FCRL4 | c.1131G>T p.V377= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV54865962; called by muse, mutect2, varscan2
- GALNT13 | c.66C>G p.V22= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV101222735; called by muse, mutect2, varscan2
- GRM3 | c.903C>T p.D301= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV64475973; called by muse, mutect2
- ICAM5 | c.204G>A p.E68= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV99320729; called by muse, mutect2, varscan2
- IL11 | c.27G>A p.L9= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV99214968; called by muse, mutect2, varscan2
- IYD | c.603C>T p.F201= | Silent (SNP) | VAF 28/98 reads (29%) | catalogued as rs531915010, COSV99989585; called by muse, mutect2, varscan2
- KPTN | c.927C>T p.S309= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as rs759768727, COSV99369869; called by muse, mutect2, varscan2
- LILRA1 | c.657C>T p.V219= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as COSV99251867; called by muse, mutect2, varscan2
- LMTK3 | c.3939C>T p.V1313= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs1252291528, COSV99540384; called by muse, mutect2
- LRRK2 | c.5109A>G p.G1703= | Silent (SNP) | VAF 8/91 reads (9%) | catalogued as COSV54149858; called by muse, mutect2, varscan2
- MBD3L1 | c.204G>A p.Q68= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV59775786, COSV99977980; called by muse, mutect2, varscan2
- MBTPS1 | c.873C>T p.D291= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as rs762887983, COSV100597538; called by muse, mutect2, varscan2
- MICAL2 | c.1044C>T p.N348= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV99817233; called by muse, mutect2, varscan2
- MYLK3 | c.1671G>A p.V557= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV101189107; called by muse, mutect2, varscan2
- NSD1 | c.1674C>T p.L558= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as COSV100728861; called by muse, mutect2, varscan2
- NUTM1 | c.240C>T p.L80= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs1338066435, COSV100412240; called by muse, mutect2, varscan2
- OR5AU1 | c.615C>T p.F205= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV100436113; called by muse, mutect2, varscan2
- OR5L2 | c.189C>T p.L63= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as rs1437390124, COSV65723825, COSV65724364; called by muse, mutect2, varscan2
- OR8H3 | c.426C>T p.L142= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV100538906; called by muse, mutect2, varscan2
- ORMDL2 | c.249G>T p.L83= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV99670692; called by muse, mutect2, varscan2
- PCNX4 | c.45C>T p.F15= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV100470202; called by muse, mutect2, varscan2
- PLA2G6 | c.180C>G p.V60= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV100140359; called by muse, mutect2, varscan2
- PSMB7 | c.237C>T p.F79= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV99412841; called by muse, mutect2, varscan2
- PSTPIP1 | c.729C>T p.V243= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV99143651; called by muse, mutect2, varscan2
- RAPGEFL1 | c.792C>T p.D264= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV99228878; called by muse, mutect2, varscan2
- RECQL5 | c.2685G>A p.L895= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV100511909; called by muse, mutect2, varscan2
- RYR2 | c.7740G>A p.L2580= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV100769641; called by muse, mutect2, varscan2
- SAMM50 | c.87T>C p.V29= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as rs11547245, COSV100601331; called by muse, mutect2, varscan2
- SBF2 | c.1671C>T p.I557= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as COSV99813964; called by muse, varscan2
- SDS | c.675G>A p.V225= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV99785281; called by muse, varscan2
- SFSWAP | c.2328G>A p.S776= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs186173251; called by muse, mutect2, varscan2
- SNX1 | c.1434G>A p.V478= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV99976086; called by muse, mutect2, varscan2
- SYDE1 | c.2115G>A p.A705= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs770749142, COSV99654781; called by muse, varscan2
- SZT2 | c.8727G>A p.L2909= (on ENST00000634258 / NM_001365999.1; = p.L2852= on NM_015284.4) | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV100987175; called by muse, mutect2
- TAS2R40 | c.423G>A p.L141= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV101282990; called by muse, mutect2, varscan2
- TBC1D4 | c.2868G>A p.L956= | Silent (SNP) | VAF 23/157 reads (15%) | catalogued as COSV100884584; called by muse, mutect2, varscan2
- TMEFF1 | c.207G>A p.V69= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as COSV100614623; called by muse, mutect2, varscan2
- TRDN | c.1344G>A p.E448= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as COSV100521697, COSV62126156; called by muse, mutect2, varscan2
- TUBGCP6 | c.3918C>T p.L1306= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV99955399; called by muse, mutect2, varscan2
- USH2A | c.6711C>T p.D2237= | Silent (SNP) | VAF 33/62 reads (53%) | catalogued as rs138959688, COSV100230801, COSV56354234; called by muse, mutect2, varscan2
- ZNF175 | c.978G>C p.L326= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs765680203, COSV99219430; called by muse, mutect2, varscan2
- ZNF611 | c.1993C>T p.L665= | Silent (SNP) | VAF 33/190 reads (17%) | catalogued as COSV100160224; called by muse, mutect2, varscan2
- ZNF615 | c.1050A>G p.G350= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV100943768; called by muse, mutect2, varscan2
- AK6 | chr5:69369665 C>G | 5'Flank (SNP) | VAF 6/36 reads (17%) | catalogued as COSV51456614, COSV99281368; called by muse, mutect2, varscan2
- ANKRD7 | c.179+2937C>A | Intron (SNP) | VAF 31/137 reads (23%) | catalogued as COSV99501068; called by muse, mutect2, varscan2
- HAPLN1 | c.*1A>C | 3'UTR (SNP) | VAF 24/71 reads (34%) | catalogued as COSV99164806; called by muse, mutect2, varscan2
- SNORD115-21 | n.30G>A | RNA (SNP) | VAF 17/61 reads (28%) | called by muse, mutect2, varscan2
- SNORD116-17 | n.42G>A | RNA (SNP) | VAF 18/131 reads (14%) | called by muse, mutect2, varscan2
- STON1 | chr2:48529952 G>C | 5'Flank (SNP) | VAF 26/82 reads (32%) | catalogued as COSV101284466; called by muse, mutect2, varscan2
